Gene-level copy-number profile of tumor specimen TCGA-HU-8604-01A from TCGA case TCGA-HU-8604, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 82.6 years (30,178 days).
Specimen TCGA-HU-8604-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.3ff5a236-6b06-4717-ac2e-1c6f67f8d85f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-8604-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6e47a378-24d8-4857-afb4-3b7b5d5d2599

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 295; copy number 2: 18,855; copy number 3: 2,305; copy number 4: 24,802; copy number 5: 9,528; copy number 6: 3,810; copy number 10: 3; copy number 11: 8; copy number 12: 52; copy number 14: 98; copy number 26: 2; copy number 27: 7; copy number 54: 4; copy number 57: 1; copy number 58: 5; copy number 59: 5; copy number 60: 9; copy number 73: 19; copy number 84: 3; copy number 99: 2; copy number 126: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-8604-01A-11D-2390-01): tumor purity 0.26, ploidy 2.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 219 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:43,571,594–44,389,706, 8 genes, copy number 11 (within-gene range 6–11): NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10.
- chr6:4,529,722–4,611,919, 3 genes, copy number 10: AL133393.1, AL034376.1, KU-MEL-3.
- chr9:14,475–746,106, 19 genes, copy number 73 (within-gene range 6–73): WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1.
- chr9:5,450,503–5,776,557, 5 genes, copy number 59 (within-gene range 6–59): CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1.
- chr9:6,007,826–6,066,714, 3 genes, copy number 84: MIR4665, RANBP6, AL162384.1.
- chr9:7,304,551–10,612,723, 15 genes, copy number 26–126 (within-gene range 2–126): AL157703.1, RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1, PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P.
- chr9:12,685,439–12,885,417, 5 genes, copy number 60 (within-gene range 5–60): TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA.
- chr9:15,163,622–15,510,995, 5 genes, copy number 58 (within-gene range 2–58): TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1.
- chr9:21,453,802–21,559,900, 1 gene, copy number 54 (within-gene range 2–54): MIR31HG.
- chr9:21,512,115–21,699,596, 5 genes, copy number 54–99: MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P.
- chr17:17,843,511–20,447,224, 150 genes, copy number 12–14 (within-gene range 6–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 295. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
